Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A6K1, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A6K1-01A (Primary Tumor).

[page 1 of 3]
M

(180.0cm 80.6kg BSA: 2.01m²)

Accession:

Specimen Date/Time:

Carcinoma, squamous cell NOS
Site Larynx NOS
ICD O-3
8070/3
QW8/9/13
232.9

DIAGNOSIS

(A) TOTAL LARYNGECTOMY, BILATERAL NECK DISSECTION II-IV, AND RIGHT HEMITHYROID :

INVASIVE SQUAMOUS CARCINOMA, -- Moderately differentiated

Tumor Features:

Gross: Exophytic
Size: 3.2 cm in largest dimension
Invasion: Present, depth 1.1 cm
Tumor Border: Infiltrative with thick cords > 4 cells
Perineural Invasion: Not identified
Vascular Invasion: Absent
Bone / Cartilage Invasion: Cartilage invasion Present
Lymphocyte Infiltration: Moderate

Right thyroid lobe: Thyroid parenchyma with chronic lymphocytic thyroiditis, negative for tumor
Stoma site: Acute and chronic inflammation, granulation tissue, negative for tumor.
Six lymph nodes, no tumor present.

Right neck dissection

No tumor present in 13 Lymph Nodes.

Level I:

Positive Nodes = 0
Total Nodes = 6

Level III:

Positive Nodes = 0
Total Nodes = 2

Level IV:

Positive Nodes = 0
Total Nodes = 5
One lymph node, with hyalanized necrotic nodule, favor granuloma

Left neck dissection

No tumor present in 29 Lymph Nodes.

Level II:

Positive Nodes = 0
Total Nodes = 18

Level III:

Positive Nodes = 0
Total Nodes = 7

Level IV:

Positive Nodes = 0
Total Nodes = 4

(B) POSTERIOR CRICOID MARGIN, NEW MARGIN

[page 2 of 3]
Accession:

X

(180.0cm 30.6kg BSA: 2.01m²)

Specimen Date/Time:

- Squamous mucosa, no tumor present.
(C) RIGHT LATERAL PHARYNX
Squamous mucosa, no tumor present.
(D) LEFT LATERAL PHARYNX
Squamous mucosa, no tumor present.
(E) BASE OF TONGUE
Squamous mucosa, no tumor present.
(F) TRACHEA
Respiratory mucosa, no tumor present.
(G) LEFT SUPERIOR MEDIASTINAL TISSUE
Two lymph nodes, negative for tumor (0/2)

GROSS DESCRIPTION

(A) TOTAL LARYNGECTOMY, BILATERAL NECK DISSECTION II-IV, AND RIGHT HEMITHYROID - A total laryngectomy specimen with attached bilateral neck dissection, overall 11.5 x 7.5 x 6.5 cm, including larynx (11.5 x 6.0 x 4.1 cm), attached right thyroid lobe (4.1 x 3.0 x 0.9 cm) right neck soft tissue (10.5 x 5.1 x 1.1 cm), and attached left neck soft tissue (9.5 x 4.1 x 1.1 cm), and attached skin with continuous stoma (3.3 x 3.0 x 2.5 cm).

There is a right transglottic ulcerated/fungating mass lesion (3.2 x 2.3 x 0.5 cm, 3.5 cm from the distal end of resection). On cut surface, the tumor has a depth of invasion (1.1 cm) and invades into and through the thyroid cartilage.

A stoma site is identified (1.8 x 2.0 cm) that is continuous through the anterior tracheal cartilage to the center of the skin resection attached on the superficial anterior surface.

The right thyroid lobe has a homogenous tan-brown cut surface with no distinct lesions.

The right level II-IV neck dissection yields twenty possible lymph nodes.

The left neck dissection, level II-IV yields thirty-three possible lymph nodes.

SECTION CODE: A1-A6, tumor submitted from right to left (A1-A2, continuous cross section superior to inferior, A3-A4, continuous cross section superior to inferior, A5-A6, continuous cross section superior to inferior); A7, left vocal cord representative section; A8, stoma representative section; A9, thyroid, representative section; A10-A19, lymph nodes from right neck dissection, level II-IV (A10-A14, level II: A10, five possible lymph nodes; A11, one lymph node serially sectioned; A12, one lymph node serially sectioned; A13, one lymph node bisected); (level III: A14-A17, A14, one lymph node serially sectioned; A15, one lymph node serially sectioned; A16, one lymph node serially sectioned; A17, one lymph node bisected); (level IV: A18, A19; A18, four possible lymph nodes; A19, five possible lymph nodes); left neck dissection lymph nodes, level II-IV, A20-A27: (level II, A20, four possible lymph nodes; A21, seven possible lymph nodes; A22, six possible lymph nodes; A23, two possible lymph nodes; A24, four possible lymph nodes, level III, A25-A26: A25, three possible lymph nodes; A26, three possible lymph nodes; level IV: A27, four possible lymph nodes).

(B) POSTERIOR CRICOID MARGIN, NEW MARGIN INKED - Received is a tan, pink, strip of soft tissue (1.9 x 0.3 x 0.1 cm). One surface has been inked by the surgeon. This is reinked in black. The specimen is entirely embedded in one block for frozen section analysis.

*FS/DX: NO TUMOR PRESENT.

(C) RIGHT LATERAL PHARYNX - Received is a tan, pink, strip of tissue (4 x 0.3 x 0.1 cm). Specimen is entirely embedded in one block for frozen section analysis.

*FS/DX: NO TUMOR PRESENT.

(D) LEFT LATERAL PHARYNX - Received is a tan, pink, strip of tissue (3.6 x 0.1 x 0.1 cm). Specimen is entirely embedded in one block for frozen section analysis.

*FS/DX: NO TUMOR PRESENT.

(E) BASE OF TONGUE - Received is a tan, pink, strip of soft tissue (4 x 0.1 x 0.1 cm). One surface has been inked, this is reinked in blue. The specimen is entirely embedded in one block for frozen section analysis.

*FS/DX: NO TUMOR PRESENT.

(F) TRACHEA - Received is a tan, pink, irregularly shaped tissue (1.1 x 0.1 x 0.1 cm). The specimen is entirely embedded in one

[page 3 of 3]
Accession:

3

(180.0cm 80.6kg BSA: 2.01m²)

Specimen Date/Time:

block for frozen section analysis.

*FS/DX: NO TUMOR PRESENT.

(G) LEFT SUPERIOR MEDIASTINAL TISSUE - A portion of tan-pink soft tissue (3.0 x 2.0 x 0.8 cm) that is serially sectioned to reveal a tan-gray cut surface. The specimen is submitted entirely in G1-G3.

CLINICAL HISTORY

SNOMED CODES

M-80703, M-43000, "Some tests reported here may have been developed and performance characteristics determined by tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

These

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file c3875ff1-9c44-492f-8474-68132acd4afe (TCGA-CV-A6K1.10950DBE-29F6-4A4B-AFC5-2C25AE608901.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).